Gene-level copy-number profile of tumor specimen TARGET-20-PARVUA-03A from TARGET case TARGET-20-PARVUA, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 15.8 years (5,786 days).
Specimen TARGET-20-PARVUA-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-AML.5bc21053-fe94-54df-b7bf-6c1e4c61c323.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-20-PARVUA-14A (bone marrow normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 364 have no estimate.
https://portal.gdc.cancer.gov/files/2dbdc91e-f1ad-4c39-852b-f750789d2c14

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 1,449; copy number 1: 2,643; copy number 2: 48,487; copy number 3: 6,272; copy number 4: 1,170; copy number 5: 111; copy number 6: 113; copy number 7: 5; copy number 8: 8; copy number 11: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 238 genes in 60 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:84,477,039–84,574,480, 6 genes, copy number 6 (within-gene range 2–6): AL844170.1, RPF1, GNG5, AL359762.3, SPATA1, CTBS.
- chr1:108,508,574–108,644,900, 2 genes, copy number 5: AL392088.1, FAM102B.
- chr1:171,670,517–171,762,524, 6 genes, copy number 6: PFN1P1, RPL4P3, VAMP4, Z98751.1, Z98751.3, Z98751.2.
- chr1:247,175,256–247,257,210, 10 genes, copy number 5–11: AL390728.3, AL390728.2, AL390728.6, AL390728.4, MIR3916, RNA5SP82, AL390728.5, AL390728.1, VN1R17P, VN1R5.
- chr2:189,661,385–189,877,629, 9 genes, copy number 6 (within-gene range 3–6): ASNSD1, ASDURF, AC012488.2, ANKAR, OSGEPL1, OSGEPL1-AS1, AC013468.1, ORMDL1, PMS1.
- chr2:194,129,354–194,188,309, 2 genes, copy number 5: GLULP6, HNRNPA1P47.
- chr2:208,236,229–208,358,746, 4 genes, copy number 6: IDH1, IDH1-AS1, PIKFYVE, MYL6BP1.
- chr3:32,592,972–32,635,554, 3 genes, copy number 5: AC104306.2, IGBP1P3, RPL30P4.
- chr3:146,064,042–146,251,179, 4 genes, copy number 5–6: AC107021.1, LNCSRLR, PLOD2, PLSCR4.
- chr3:146,391,363–146,544,856, 4 genes, copy number 5: AC069528.1, PLSCR2, AC069528.2, PLSCR1.
- chr4:73,980,811–74,099,196, 10 genes, copy number 5: PF4, PPBP, CXCL5, AC097709.1, RN7SL218P, CXCL3, PPBPP2, AC093677.3, AC093677.1, CXCL2.
- chr4:112,116,510–112,231,596, 4 genes, copy number 5: AC093663.1, FAM241A, AC093663.2, AC109347.1.
- chr4:153,640,168–153,760,024, 5 genes, copy number 5 (within-gene range 2–5): AC106865.1, WDR45P1, TLR2, RNF175, AC020703.1.
- chr5:42,917,414–42,997,480, 4 genes, copy number 6 (within-gene range 2–6): PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2.
- chr5:159,100,483–159,286,036, 7 genes, copy number 5: LINC02202, AC134043.3, RNF145, AC134043.2, LINC01932, AC134043.1, UBLCP1.
- chr5:159,314,780–159,330,487, 2 genes, copy number 5: IL12B, RNU4ATAC2P.
- chr6:4,018,713–4,189,806, 10 genes, copy number 5: AL138831.2, AL138831.1, PRPF4B, FAM217A, C6orf201, ECI2, AL136309.3, ECI2-DT, AL136309.2, AL136309.1.
- chr6:79,914,814–80,084,776, 8 genes, copy number 6 (within-gene range 2–6): ELOVL4, AL133475.1, GAPDHP63, RPL35AP18, TTK, AL591135.2, AL591135.1, AK4P5.
- chr7:90,119,299–90,164,829, 3 genes, copy number 5: AC004969.1, DPY19L2P4, STEAP1.
- chr8:33,473,386–33,540,493, 6 genes, copy number 5: TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18.
- chr8:48,710,789–49,076,093, 7 genes, copy number 6–7: EFCAB1, AC100805.1, AC013701.1, SNAI2, AC013701.2, AC044893.2, PPDPFL.
- chr8:53,966,552–54,192,035, 9 genes, copy number 6: TCEA1, AC100821.1, AC100821.2, LYPLA1, TDGF1P5, Metazoa_SRP, MRPL15, RNU6ATAC32P, AC060764.1.
- chr8:58,503,588–58,659,853, 4 genes, copy number 6: PPIAP85, SDCBP, NSMAF, AC068522.1.
- chr8:66,562,175–67,083,783, 14 genes, copy number 6: MYBL1, VCPIP1, Y_RNA, C8orf44-SGK3, C8orf44, SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87, TCF24, PPP1R42, AC110998.1, COPS5.
- chr8:132,685,007–132,848,807, 3 genes, copy number 6 (within-gene range 3–6): TMEM71, AF228727.1, PHF20L1.
- chr8:144,930,358–145,066,685, 8 genes, copy number 8: ZNF16, ZNF252P, AF235103.1, TMED10P1, ZNF252P-AS1, AF235103.2, AC139103.1, C8orf33.
- chr9:5,084,999–5,193,558, 13 genes, copy number 6: PDSS1P1, MTND6P5, MTND1P11, MTCO1P11, MTCO2P11, MTATP6P11, MTCO3P11, MTND4P14, MTND5P14, TCF3P1, IGHEP2, INSL6, AL133547.1.
- chr9:27,495,857–27,573,866, 4 genes, copy number 5 (within-gene range 2–5): AL451123.2, IFNK, AL451123.1, C9orf72.
- chr9:105,447,796–105,776,629, 8 genes, copy number 5 (within-gene range 2–5): FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1.
- chr10:43,628,817–43,674,703, 7 genes, copy number 5: ZNF32-AS3, AL645634.2, RPL21P88, ZNF32, ZNF32-AS1, ZNF32-AS2, AL645634.1.
- chr10:58,191,517–58,305,621, 3 genes, copy number 6 (within-gene range 2–6): IPMK, CISD1, AC016396.1.
- chr11:34,915,829–35,020,591, 2 genes, copy number 6 (within-gene range 2–6): PDHX, MIR1343.
- chr11:74,311,362–74,398,433, 3 genes, copy number 6 (within-gene range 2–6): P4HA3-AS1, PGM2L1, HNRNPA1P40.
- chr11:90,193,614–90,226,538, 3 genes, copy number 6: AP000648.4, CHORDC1, AP002364.1.
- chr12:25,195,216–25,250,936, 4 genes, copy number 5: ETFRF1, KRAS, AC092794.1, AC092794.2.
- chr12:30,086,342–30,217,916, 3 genes, copy number 6 (within-gene range 2–6): AC023511.3, AC023511.2, AC023511.1.
- chr12:76,036,585–76,084,735, 2 genes, copy number 6: NAP1L1, AC011611.5.
- chr13:21,260,015–21,348,721, 5 genes, copy number 5 (within-gene range 2–5): ESRRAP2, AL158032.2, MIPEPP3, LINC00539, GRK6P1.
- chr16:64,242,608–64,343,909, 2 genes, copy number 5: AC012322.1, AC093536.1.
- chr20:10,385,779–10,434,222, 4 genes, copy number 5: SDAD1P2, MKKS, AL034430.1, AL034430.2.

Autosomal genes at a single copy (total copy number 1): 1,723. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
